Gene-level copy-number profile of tumor specimen TCGA-91-6828-01A from TCGA case TCGA-91-6828, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.8 years (25,870 days).
Specimen TCGA-91-6828-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.8ffb5e7f-f03f-488d-82ab-11f1fae515dd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-6828-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f9e63d4f-1dad-4abb-bc6e-6f2868b70f9d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 852; copy number 1: 26,885; copy number 2: 29,937; copy number 3: 225; copy number 4: 235; copy number 5: 479; copy number 6: 1,054; copy number 8: 96; copy number 9: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-6828-01A-11D-1854-01): tumor purity 0.37, ploidy 4.62, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 852 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:19,878,555–32,641,615, 470 genes (within-gene range 0–1) (broad region; genes not listed).
- chr15:36,579,626–36,810,248, 1 gene (within-gene range 0–1): CDIN1.
- chr15:36,641,186–50,546,708, 381 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,682 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:57,492,884–145,066,685, 1,354 genes, copy number 5–6 (broad region; genes not listed).
- chr12:25,936,683–26,421,462, 12 genes, copy number 5: RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1.
- chr12:26,335,864–26,373,733, 2 genes, copy number 5: AC055720.2, RNA5SP354.
- chr12:30,696,121–31,591,136, 30 genes, copy number 5 (within-gene range 3–5): AC012673.1, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2.
- chr20:30,484,925–31,801,805, 36 genes, copy number 5 (within-gene range 1–5): 5_8S_rRNA, AC018688.1, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2.
- chr20:34,688,688–36,773,818, 78 genes, copy number 6 (broad region; genes not listed).
- chr20:51,098,138–61,083,750, 168 genes, copy number 5–9 (broad region; genes not listed).
- chr20:61,267,525–61,370,855, 2 genes, copy number 5: AL365229.1, BX640515.1.

Autosomal genes at a single copy (total copy number 1): 24,498. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
